Gene-level copy-number profile of tumor specimen ALCH-B3K4-TTP1-A from ALCHEMIST case ALCH-B3K4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.3 years (21,284 days).
Specimen ALCH-B3K4-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b91519a7-db19-46b2-82cc-909bd4eb6a01.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3K4-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/a747620e-ab17-4de5-8c1d-ccddffc5bae4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 8,025; copy number 2: 46,315; copy number 3: 1,945; copy number 4: 1,149; copy number 5: 116; copy number 6: 610; copy number 7: 20; copy number 8: 88; copy number 9: 82; copy number 11: 12; copy number 16: 8.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,252,211–89,254,015, 2 genes: IGKV3-31, IGKV1-32.
- chr2:90,359,809–91,580,863, 4 genes: AC233263.1, AC233263.7, AC233266.1, AC233266.2.
- chr2:219,482,073–219,516,877, 5 genes (within-gene range 0–2): ASIC4-AS1, AC053503.6, SPEGNB, AC053503.4, GMPPA.
- chr16:33,907,419–33,950,420, 4 genes: ARHGAP23P1, IGHV3OR16-7, AC140658.4, IGHV3OR16-16.
- chr21:10,649,400–13,120,807, 6 genes: IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 936 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–43,313,512, 649 genes, copy number 6–9 (broad region; genes not listed).
- chr5:51,275,253–52,990,278, 20 genes, copy number 11–16 (within-gene range 4–16): AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2, RNA5SP182, KATNBL1P4, AC091903.1, LINC02118, RPS17P11, MFSD4BP1, AC022126.1, PELO, ITGA1, AC022133.2, B3GNTL1P1, AC022133.1, AC025180.1.
- chr12:65,758,020–69,738,574, 91 genes, copy number 5 (broad region; genes not listed).
- chr17:62,910,021–63,427,699, 12 genes, copy number 7 (within-gene range 1–7): AC005972.3, MIR633, TRMT112P3, AC005972.1, AC005972.2, TANC2, AC006270.2, AC006270.1, DNAJB6P8, AC015923.1, AC005828.2, AC005828.7.
- chr17:64,477,785–64,919,480, 26 genes, copy number 9: POLG2, ATP5MFP4, DDX5, MIR3064, MIR5047, CEP95, SMURF2, AC009994.1, MICOS10P2, ARHGAP27P1-BPTFP1-KPNA2P3, KPNA2P3, AC132812.1, BPTFP1, AC103810.3, PLEKHM1P1, MIR6080, MIR4315-2, RNU7-115P, AC103810.9, LRRC37A3, RN7SL404P, AC103810.6, AC103810.7, AC103810.2, AC103810.5, RDM1P4.
- chr17:66,835,117–69,327,244, 73 genes, copy number 7–8 (broad region; genes not listed).
- chr17:70,628,917–71,298,218, 5 genes, copy number 6: AC005771.1, AC007423.1, AC005181.1, CASC17, RNU7-155P.
- chr17:72,021,851–73,092,712, 16 genes, copy number 8: ROCR, LINC01152, AC007461.1, SOX9-AS1, LINC02097, SOX9, LINC00511, LINC02003, AC007639.1, RPL32P33, AC080037.2, SLC39A11, RN7SKP180, AC080037.1, AC011120.1, ATG12P1.
- chr19:984,332–998,438, 1 gene, copy number 5: WDR18.
- chr20:10,435,305–10,994,924, 7 genes, copy number 5 (within-gene range 2–5): SLX4IP, AL035456.1, JAG1, MIR6870, AL050403.2, LINC01752, AL135937.1.
- chr20:10,996,293–13,008,417, 19 genes, copy number 6–7: LINC02871, AL158042.1, AL049649.1, RPS11P1, AL109837.1, PGAM3P, AL161938.1, LINC00687, RN7SKP111, AL080274.1, BTBD3, AL035448.1, AL109838.1, AL136460.1, PA2G4P2, LINC01722, AL078623.1, AL133331.1, LINC01723.
- chr20:38,378,825–38,588,463, 17 genes, copy number 5: AL391095.2, AL391095.1, AL391095.3, SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D, SNORA71, SNHG11, SNORA71E, SNORA60, RALGAPB, MIR548O2, RPS3P2, ADIG.

Autosomal genes at a single copy (total copy number 1): 8,025. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
